Gene-level copy-number profile of tumor specimen TCGA-CN-6012-01A from TCGA case TCGA-CN-6012, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.5 years (24,286 days).
Specimen TCGA-CN-6012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0806dda4-563b-438b-b553-dd31c940eaf0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6012-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/437cad44-0537-4ecd-b012-cfaebba1f561

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 868; copy number 3: 14,896; copy number 4: 13,952; copy number 5: 14,176; copy number 6: 7,349; copy number 7: 3,516; copy number 8: 1,024; copy number 9: 991; copy number 11: 1,937; copy number 12: 765; copy number 13: 28; copy number 22: 252; copy number 36: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6012-01A-11D-1682-01): tumor purity 0.62, ploidy 1.6, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 8,571 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,372,668–121,580,524, 125 genes, copy number 7 (broad region; genes not listed).
- chr1:224,107,282–241,357,230, 402 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 11 (broad region; genes not listed).
- chr7:70,972–141,888,092, 2,569 genes, copy number 7 (broad region; genes not listed).
- chr7:141,911,217–141,947,007, 3 genes, copy number 7: OR9N1P, OR9A4, CLEC5A.
- chr8:34,784,028–76,308,315, 654 genes, copy number 8–13 (broad region; genes not listed).
- chr8:116,642,130–145,066,685, 501 genes, copy number 8–9 (broad region; genes not listed).
- chr9:26,642,697–43,045,120, 428 genes, copy number 8–9 (broad region; genes not listed).
- chr11:40,114,203–41,459,773, 1 gene, copy number 11 (within-gene range 4–11): LRRC4C.
- chr11:41,122,907–42,253,721, 11 genes, copy number 8–11: RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.
- chr11:68,460,731–71,997,597, 104 genes, copy number 22–36 (within-gene range 4–36) (broad region; genes not listed).
- chr14:18,333,726–39,216,335, 696 genes, copy number 12 (broad region; genes not listed).
- chr14:43,990,539–44,386,064, 4 genes, copy number 8 (within-gene range 5–8): LINC02307, EIF4BP1, AL109766.1, YWHAZP1.
- chr15:19,878,555–24,823,365, 182 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr18:20,946,906–43,277,535, 299 genes, copy number 8 (broad region; genes not listed).
- chr19:13,731,760–13,953,392, 17 genes, copy number 12 (within-gene range 6–12): CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1.
- chr19:36,334,453–40,591,399, 206 genes, copy number 22 (broad region; genes not listed).
- chr20:10,006,381–10,368,776, 1 gene, copy number 9 (within-gene range 5–9): SNAP25-AS1.
- chr20:10,172,522–30,289,956, 333 genes, copy number 9 (broad region; genes not listed).
- chr21:44,802,577–46,665,124, 69 genes, copy number 7 (broad region; genes not listed).
- chr22:44,492,583–50,801,309, 166 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
